Somatic mutation profile of tumor specimen C3L-04265-54 (aliquot CPT0230980002) from CPTAC case C3L-04265, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 64.3 years (23,490 days).
Specimen C3L-04265-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed7d98e3-f4c8-4632-bf7f-ae7af99f6691.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04265-50 (Buccal Cell Normal), aliquot CPT0231080001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c44a55b0-6952-4075-af43-d16aeebfdc62

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Frame Shift Ins 1, RNA 1, Intron 1, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 80/552 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- EIF5A | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 16/288 reads (6%) | catalogued as COSV59748478; called by muse, mutect2
- ERO1B | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.061); catalogued as rs966390978, COSV59242011; called by muse, mutect2, varscan2
- NPM1 | c.863_864insTATG p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 18/73 reads (25%) | catalogued as COSV51544217, COSV51551832, COSV51558469, COSV51558827, COSV51561854; called by mutect2, pindel, varscan2
- PDS5B | c.2629C>T p.R877C | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV59730783; called by muse, mutect2
- VPS13B | c.4822A>G p.R1608G | Missense Mutation (SNP) | VAF 41/361 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as rs761562870; called by muse, mutect2, varscan2
- ARID4B | c.3373G>A p.G1125R | Missense Mutation (SNP) | VAF 9/178 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); called by muse, mutect2
- ZNF726 | c.972G>C p.W324C | Missense Mutation (SNP) | VAF 40/283 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.952); called by muse, varscan2
- SUGP1 | c.1695C>T p.I565= | Silent (SNP) | VAF 22/220 reads (10%) | catalogued as rs192830644; called by muse, mutect2
- GVINP1 | n.4029T>A | RNA (SNP) | VAF 15/313 reads (5%) | called by muse, mutect2
- PRSS21 | c.91+13G>A | Intron (SNP) | VAF 37/109 reads (34%) | catalogued as rs1399819945; called by muse, mutect2
